Surgical pathology report (de-identified scan), TCGA case TCGA-VM-A8C9, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Huntsman Cancer Institute, specimen TCGA-VM-A8C9-01A (Primary Tumor).

[page 1 of 2]
Surg Path Final Report

Temporary Copy

Page 1 of 2

Case:

Collected:

Ordering by:

Patient:

Location:

ACCESSION

Submitting Physician

Clinical History

Left temporal tumor

Diagnosis

"LEFT TEMPORAL TUMOR", (RESECTION):
- DIFFUSE ASTROCYTOMA, WHO GRADE II.

ICD O-3

Astrocytoma, grade II 940013

Site
Site: Brain, supratentorial NOS C71.0
Site: Brain, temporal lobe C71.2

11/27/13

I certify that I personally conducted the
diagnostic evaluation on the above specimens
and have rendered the above diagnosis(es):

electronic signature

For questions regarding this case, call

Resident

Gross Description

A single specimen is received in formalin labeled with the patient's name, medical record number and "#1 left temporal tumor". The specimen consists of three, unoriented tan-white to gray tissue fragments, grossly consistent with brain tissue measuring 3.0 x 2.5 x 1.0 cm. The specimen is serially sectioned to reveal no focal lesions. Submitted entirely in cassettes 1A-1B.

Microscopic Examination

Sections show foci of increased cellularity within gray and white matter. The foci have infiltrative borders and are composed of cells with irregularly shaped nuclei and moderate amounts of eosinophilic cytoplasm. Frequent pleomorphic, hyperchromatic, and occasional multinucleated cells are present. No significant mitotic figures, necrosis or vascular proliferation with hyperplasia is identified.

Immunohistochemical stains are performed with appropriately reactive positive and negative controls and show the neoplastic cells to be positive for GFAP and negative for synaptophysin and NeuN.

Synoptic Report

No AJCC/UICC TNM Staging System

Protocol web posting date:

Protocol effective date:

Specimen type/procedure: Resection

Specimen handling: Unfrozen for routine permanent paraffin sections

*Specimen size: Greatest dimension: 3.0 cm

Laterality: Left

Tumor site: Brain/cerebrum: Left temporal lobe

[page 2 of 2]
Surg Path Final Report

Temporary Copy

Page 2 of 2

Case: [REDACTED]
Collected: [REDACTED]
Ordered by: [REDACTED]

Patient: [REDACTED]
ID: [REDACTED]
Location: [REDACTED]

Histologic type and grade: Diffuse astrocytoma (WHO grade II)

Histologic Grade: WHO grade II

*Ancillary studies: Immunohistochemistry:

GFAP - positive

NeuN - negative

Synaptophysin - negative

*Additional pathologic findings: None

HPV Discrepancy		✓
Time Discrepancy History		✓
Discrepancy Primary Noted		✓
Reviewed Initials	BTH	Reviewed: 10/29/2013

Source: NCI Genomic Data Commons file 30737672-3ca8-46c5-9e3d-5defc6d14c03 (TCGA-VM-A8C9.572BF80A-ECDD-4EAF-A28D-7BFB0137A598.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).